Somatic mutation profile of tumor specimen TCGA-5U-AB0D-01A (aliquot TCGA-5U-AB0D-01A-11D-A423-09) from TCGA case TCGA-5U-AB0D, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 71.6 years (26,167 days).
Specimen TCGA-5U-AB0D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49b965a8-ad5e-4b7b-a355-e933b33e8cca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5U-AB0D-10A (Blood Derived Normal), aliquot TCGA-5U-AB0D-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/765449dc-dbac-45e8-a1fd-e892f5751912

The open-access MAF lists 57 somatic variants for this specimen: 45 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 10, Nonsense Mutation 2, Intron 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL4 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs779011667, COSV99646851, COSV99647751; called by muse, mutect2, varscan2
- ANO7 | c.1627C>T p.R543C (on ENST00000274979; = p.R489C on NM_001370694.2) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.953); catalogued as rs184837414; called by muse, mutect2, varscan2
- ATP7B | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1427888614; called by muse, mutect2
- BSPRY | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs570967595, COSV65243275; called by muse, mutect2
- EVC2 | c.1192T>C p.C398R | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.917); catalogued as rs1173102415; called by muse, mutect2, varscan2
- FBXO15 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs761515422, COSV54043808; called by muse, mutect2, varscan2
- ITGAL | c.3288C>A p.S1096R | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63322673; called by muse, varscan2
- MECP2 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781871640, COSV100318417; called by muse, mutect2, varscan2
- OR10Z1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as rs1183030308, COSV63525505; called by muse, mutect2
- PC | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752901945; called by muse, mutect2, varscan2
- PCDHGA5 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs577848371; called by muse, varscan2
- POLR3K | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs770284903; called by muse, mutect2, varscan2
- RIOK2 | c.1116C>A p.D372E | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs765760583; called by muse, mutect2, varscan2
- RPS2 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs367578393; called by muse, mutect2, varscan2
- SCAP | c.3743G>A p.R1248H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs185806499, COSV55545716; called by muse, mutect2, varscan2
- SPOCD1 | c.3238C>T p.P1080S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs752265114; called by muse, mutect2, varscan2
- TAF3 | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs779441787; called by muse, mutect2, varscan2
- TOGARAM1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); catalogued as rs1043458621, COSV61888088; called by muse, mutect2
- TSPAN18 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763195686; called by muse, mutect2, varscan2
- ACP2 | c.669G>A p.W223* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- ADAM17 | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRG6 | c.3049G>A p.D1017N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ALAS2 | c.1148A>T p.D383V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C4orf45 | c.35C>A p.T12N | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CHST10 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- FAM47A | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- FRMPD3 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- GMCL1 | c.431G>T p.S144I | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- GNPDA2 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- HTATSF1 | c.1815C>A p.D605E | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1328 | c.1060C>A p.P354T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- NF1 | c.8062G>A p.V2688M (on ENST00000358273 / NM_001042492.3; = p.V2667M on NM_000267.3) | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NRDC | c.1984-1G>A p.X662_splice | Splice Site (SNP) | VAF 30/109 reads (28%) | called by muse, mutect2, varscan2
- OGT | c.2885G>A p.C962Y | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- PLA2G4C | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PQBP1 | c.683A>T p.K228M | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC17A4 | c.1012T>C p.F338L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SLC45A2 | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOX4 | c.1210_1213dup p.L405Rfs*12 | Frame Shift Ins (INS) | VAF 19/23 reads (83%) | called by mutect2, pindel, varscan2
- SYTL2 | c.2033G>A p.G678D (on ENST00000528231 / NM_001162951.2; = p.G654D on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- TMEM38B | c.297C>A p.D99E | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM94 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- VBP1 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 82/534 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF189 | c.403A>G p.N135D | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ZNF479 | c.140A>T p.E47V | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDC25B | c.1233C>T p.D411= (on ENST00000245960 / NM_021873.3; = p.D397= on NM_004358.4) | Silent (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- KCNA7 | c.1302C>T p.D434= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs145070146; called by muse, mutect2, varscan2
- PRUNE2 | c.1791C>T p.S597= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs1184389833; called by muse, mutect2, varscan2
- PTGES | c.222C>T p.N74= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs200924207; called by muse, mutect2, varscan2
- SEC31B | c.3540A>G p.*1180= | Silent (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- SORCS2 | c.612C>T p.I204= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs757328456, COSV100214031; called by muse, mutect2, varscan2
- TOP1MT | c.141C>T p.H47= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs141679480; called by muse, mutect2, varscan2
- TRIM6 | c.207G>A p.R69= | Silent (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- UBR1 | c.3870C>A p.I1290= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV51928054; called by muse, mutect2, varscan2
- ZNF432 | c.1125C>T p.C375= | Silent (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-179859G>A | Intron (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- RBCK1 | c.167+512C>T | Intron (SNP) | VAF 8/58 reads (14%) | catalogued as rs764429530; called by muse, mutect2, varscan2
